Gene-level copy-number profile of tumor specimen TCGA-AX-A3G3-01A from TCGA case TCGA-AX-A3G3, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 58.3 years (21,308 days).
Specimen TCGA-AX-A3G3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.61f0069a-e832-442a-aa11-0e06d7474da8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AX-A3G3-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 820 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5c0936d1-b0c2-4278-8006-b712c308c3f6

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 28; copy number 1: 2,720; copy number 2: 14,408; copy number 3: 14,765; copy number 4: 15,507; copy number 5: 6,122; copy number 6: 2,731; copy number 7: 1,279; copy number 8: 1,058; copy number 9: 1,150; copy number 10: 11; copy number 11: 8; copy number 14: 16.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-AX-A3G3-01): tumor purity 0.65, ploidy 3.47, whole-genome doublings 1 (call status: snp_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,185 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:119,428,949–184,457,891, 1,150 genes, copy number 9 (within-gene range 3–9) (broad region; genes not listed).
- chr7:151,806,490–152,436,003, 11 genes, copy number 10 (within-gene range 6–10): AC093583.1, PRKAG2-AS1, RNU6-604P, Y_RNA, AC074257.1, GALNTL5, Metazoa_SRP, GALNT11, AC006017.1, YBX1P4, KMT2C.
- chr9:129,575,117–129,636,135, 3 genes, copy number 11 (within-gene range 4–11): AL391056.1, NTMT1, C9orf50.
- chr18:37,565,281–40,247,367, 21 genes, copy number 11–14: AC009899.1, MIR4318, RPL12P40, AC108452.1, AC100781.1, RN7SKP182, RNU6-706P, MIR924HG, AC011139.1, RPL7AP66, MIR924, AC099845.1, MIR5583-2, MIR5583-1, RNU6-1242P, LINC01901, LINC01902, AC011266.1, LINC01477, RPL17P45, AC068688.1.

Autosomal genes at a single copy (total copy number 1): 1,587. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
